MMRF case MMRF_1388 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/85e1a95c-030d-4e6a-ad2c-e468de783b41

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 81.2 years (29,667 days); ISS stage: III; Days to last known disease status: 1,429 days (3.9 years); Days to last follow up: 1,429 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 383 days (1.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 3 (ECOG 0): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 385 mg/dL; Immunoglobulin G 5.77 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 12.9 µg/mL; Hemoglobin 3.78 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 274 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.25 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 6 mmol/L; C-Reactive Protein 1.5 mg/dL.
- Day 86: Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Beta 2 Microglobulin 5.37 µg/mL; Hemoglobin 6.88 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 221 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 6.22 mmol/L.
- Day 173: Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Hemoglobin 6.51 mmol/L; Leukocytes 10.1 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 303 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.03 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.01 mmol/L.
- Day 244: Serum Free Immunoglobulin Light Chain, Kappa 10.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.5 mg/dL; Lactate Dehydrogenase 4.2 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 14.1 ×10⁹/L; Absolute Neutrophil 13.1 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 7.65 mmol/L.
- Day 320 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Lactate Dehydrogenase 4.03 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 5.56 mmol/L.
- Day 481 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.42 mg/dL; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 328 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 35 g/L; Total Protein 7.2 g/dL; Glucose 7.37 mmol/L.
- Day 605 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 7.74 g/L; Immunoglobulin A 3.07 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 212 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 6.6 mmol/L.
- Day 799 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.46 mg/dL; Immunoglobulin G 8.77 g/L; Immunoglobulin A 3.29 g/L; Immunoglobulin M 0.65 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 221 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.5 mmol/L; Albumin 39 g/L; Total Protein 7.6 g/dL; Glucose 5.5 mmol/L.
- Day 897 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.93 mg/dL; Beta 2 Microglobulin 0.4 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 194 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.48 mmol/L; Albumin 35 g/L; Total Protein 7 g/dL; Glucose 7.26 mmol/L.
- Day 988 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.01 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 3.88 g/L; Immunoglobulin M 1.38 g/L; Beta 2 Microglobulin 0.5 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 319 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 7.8 g/dL; Glucose 5.78 mmol/L.
- Day 1,163 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.1 mg/dL; Beta 2 Microglobulin 0.4 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 326 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 7.7 g/dL; Glucose 5.56 mmol/L.
- Day 1,429 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.9 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 3.68 g/L; Immunoglobulin M 1.04 g/L; Beta 2 Microglobulin 4.99 µg/mL; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 319 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.53 mmol/L; Albumin 38 g/L; Total Protein 8.3 g/dL; Glucose 6.77 mmol/L.

Other clinical attributes
- Day 3: Weight: 59 kg; Height: 154 cm.

Biospecimens (2 samples)
- Sample MMRF_1388_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 3 days.
- Sample MMRF_1388_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 3 days.
